Somatic mutation profile of tumor specimen TCGA-VS-A9UT-01A (aliquot TCGA-VS-A9UT-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.8 years (26,603 days).
Specimen TCGA-VS-A9UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 518aadac-0338-416c-8adb-201ca4dcd4b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UT-10A (Blood Derived Normal), aliquot TCGA-VS-A9UT-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ae638e1-7634-48f9-9c6a-e332a86270d5

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, Nonsense Mutation 4, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519931, COSV55878215, COSV55881107, COSV55917331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- AMOT | c.2148C>A p.N716K (on ENST00000371959 / NM_001113490.1; = p.N307K on NM_133265.3) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV100495039; called by muse, mutect2
- BCL6 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV51649830; called by muse, mutect2, varscan2
- DOCK3 | c.3089T>C p.F1030S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.694); catalogued as COSV99811804; called by muse, mutect2, varscan2
- DOK3 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100467071, COSV57252644; called by muse, mutect2, varscan2
- GRK3 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.704); catalogued as rs144810352; called by muse, mutect2, varscan2
- IFIH1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs750804689, COSV55125658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC3 | c.928A>C p.S310R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99763741; called by muse, mutect2, varscan2
- LRP1B | c.4491G>T p.K1497N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101256652; called by muse, mutect2, varscan2
- MDGA2 | c.1957C>T p.R653W (on ENST00000399232 / NM_001113498.2; = p.R355W on NM_182830.4) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs754861387, COSV62078505; called by muse, mutect2, varscan2
- MYO1G | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1349062821, COSV99348502; called by muse, mutect2
- MYT1L | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as rs1486325982, COSV101220730; called by muse, mutect2, varscan2
- OR5I1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1565151589, COSV56887915; called by muse, mutect2, varscan2
- OR8K3 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV57132774; called by muse, mutect2, varscan2
- PAGE2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 45/195 reads (23%) | catalogued as COSV100892299, COSV66596059; called by muse, mutect2, varscan2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELCH | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as rs1219251716, COSV99901965; called by muse, mutect2
- SF1 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV57112566; called by muse, mutect2, varscan2
- MTCH2 | c.183dup p.A62Cfs*29 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- C4orf33 | c.192A>G p.A64= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs755910234, COSV99828907; called by muse, mutect2, varscan2
- COQ8A | c.1533G>A p.T511= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs201337210, COSV100505038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSH2 | c.597C>T p.V199= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as rs909532810, COSV61080399; called by muse, mutect2, varscan2
- DLG5 | c.1336C>T p.L446= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100967469; called by muse, mutect2, varscan2
- DMAC2 | c.576C>T p.L192= | Silent (SNP) | VAF 49/207 reads (24%) | catalogued as rs776446210, COSV99700526; called by muse, mutect2, varscan2
- DOCK5 | c.378G>A p.E126= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99376867; called by muse, mutect2, varscan2
- GGT7 | c.1023C>T p.H341= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs369976191; called by muse, mutect2, varscan2
- MARCHF4 | c.786C>A p.P262= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99814099; called by muse, mutect2
- PPP2R1B | c.810C>T p.R270= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs782639209, COSV100231950; called by muse, mutect2, varscan2
- SPTBN1 | c.4626C>T p.D1542= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs370830282; called by muse, mutect2, varscan2
- ZNF488 | c.120G>A p.E40= | Silent (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821344 A>T | 3'Flank (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- WASF4P | n.442A>C | RNA (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
